Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHL, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHL-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Summary pathology report

Street address

Left orchidectomy; seminoma; diameter 9.0 cm; no invasion of rete testis; angio-invasion present; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O-3

Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 9ed2ec62-29c9-444e-859f-4341f94eb7fd (TCGA-2G-AAHL.81F00ECA-C7BD-4EDD-ABE1-EED08C0E5F36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).